TCGA case TCGA-AX-A3GB — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/aa3ad7c0-37cf-4337-945e-cefeee801bbb

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 73.2 years (26,724 days); Year of diagnosis: 2010; Method of diagnosis: Surgical Resection; FIGO stage: Stage IB; FIGO staging edition year: 1988; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 440 days (1.2 years).
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 6.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 19.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 41 days.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.
- Follow-up contact recording only the day: day 440.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Menopause status: Postmenopausal; Risk factors: Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 87 kg; Height: 158 cm; BMI: 34.9.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AX-A3GB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 80 mg.
  Slide TCGA-AX-A3GB-01A-01-TSA: Section location: Top; Percent tumor cells: 78; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 20; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-AX-A3GB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: TAH, BSO, pelvic and paraaortic LND, intracolic omentectomy; Surgical approach at diagnosis: open.
- Follow-up form: Hypertension diagnosis: Yes; History colorectal cancer: No; New tumor event diagnosis indicator: No.
- Drug treatment: Regimen number: 1; Pharmaceutical therapy drug name: Carboplatin and Paclitaxel.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 440 days; disease-specific survival: no event (censored), 440 days; progression-free interval: no event (censored), 440 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AX-A3GB-01A-11D-A227-01): tumor purity 0.52, ploidy 2.07, whole-genome doublings 0.
